Surgical pathology report (de-identified scan), TCGA case TCGA-VM-A8CB, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Huntsman Cancer Institute, specimen TCGA-VM-A8CB-01A (Primary Tumor).

[page 1 of 4]
Surg Path Final Report

Temporary Copy

Page 1 of 2

Case

Collection

Ordered by

Referring

ID

Location

ACCESSION

Submitting Physician

Clinical History

none given

Diagnosis

1. "LEFT FRONTAL LESION", (BIOPSY):

- HIGH GRADE GLIOMA MOST CONSISTENT WITH ANAPLASTIC OLIGODENDROGLIOMA.

2. "LEFT FRONTAL LESION", (RESECTION):

- HIGH GRADE GLIOMA MOST CONSISTENT WITH ANAPLASTIC OLIGODENDROGLIOMA (WHO GRADE III).

I certify that I personally conducted the
diagnostic evaluation on the above specimens
and have rendered the above diagnosis(es):

electronic signature

For questions regarding this case, call

Frozen Section Diagnosis

Frozen section diagnosis per

1FA: "High grade glioma"

Gross Description

Two containers are received labeled with the patient's name and medical record number.

Specimen one is received fresh for frozen section labeled "left frontal lesion". The specimen is a 1.8 x 1.2 x 0.4 cm portion of pink-tan soft tissue. Half of this tissue is submitted for frozen section. Submitted in total in cassette 1FA, and 1A.

Specimen two is received in formalin labeled "left frontal lesion", is a 46.60 g portion of pink-tan focally hemorrhagic brain tissue. The tissue is 9.0 x 7.5 x 3.0 cm in aggregate. Sectioning shows a grey to dusky pink glistening cut surface. No discrete nodules are identified. Representative sections submitted in cassette 2A-2D.

Microscopic Examination

ICD-O-3

Oligodendroglioma, grade III
945113

Site: Brain, supratentorial NA
C71.0

Brain, frontal lobe
C71.1

11/27/13

[page 2 of 4]
Surg Path Final Report

Temporary Copy

Page 2 of 2

Case

Collected

Ordered by

Referral

Location

Performed.

Synoptic Report

No AJCC/UICC TNM Staging System

Protocol web posting date:

Protocol effective date:

Specimen type/procedure:

Open biopsy

Resection

Specimen handling:

Frozen section

Unfrozen for permanent paraffin sections

Other

Specify: Received in formalin for permanent sections

Specimen size:

Greatest dimension 9.0 cm

Additional dimension: 7.5 x 3.0 cm

Laterality: Left

Tumor site:

Brain, cerebrum

Left frontal

Histologic type and grade: Oligodendroglial tumors

Histologic Grade: Anaplastic oligodendroglioma (WHO grade III)

Margins: Cannot be assessed

Ancillary studies: None performed

Comments: Specimen will be sent in consultation to the
division of neuropathology.

at

[page 3 of 4]
**Addendum Report
Temporary Copy**

Page 1 of 1

Case:

Collected:

Ordered by:

Patient:

ID:

Location:

ACCESSION

Addendum Discussion

Outside consultation diagnosis from
follows:

is as

DIAGNOSIS:

BRAIN, LEFT FRONTAL LESION, BIOPSY (PART 1) AND RESECTION (PART 2),

- ANAPLASTIC OLIGODENDROGLIOMA, WHO GRADE III (SEE COMMENT).

Comment:

Evaluation of the 1p and 19q status of this neoplasm will be performed through
laboratories; the results of this testing will be issued in a separate report.

ORIGINAL DIAGNOSIS REMAINS UNCHANGED.

I certify that I personally conducted the
diagnostic evaluation on the above specimen(s)
and have rendered the above diagnosis(es):

electronic signature

[page 4 of 4]
Addendum Report
Temporary Copy

Page 1 of 1

Case

Collected

Ordered by

Patient

Location

ACCESSION

Addendum Discussion

1p/19q FISH

Fluorescence in-situ hybridization (FISH) analysis for deletions of 1p and/or 19q are performed on sections from block "2A".

Calculated 1p/1q ratio = 0.49 (<0.74 is deleted)
Calculated 19q/19p ratio = .055 (<0.88 is deleted)

The results are interpreted as deleted for 1p and 19q. This assay was read by Dr.

A result of a deleted 1p and 19q suggests a favorable prognosis. A solitary 1p deletion suggests an intermediate prognosis. A 19q solitary deletion may suggest a favorable prognosis in a smaller subset of tumors. The lack of either 1p and/or 19q deletion(s) is considered a poor prognostic indicator and may be associated with decreased disease-free survival and overall survival.

I certify that I personally conducted the
diagnostic evaluation on the above specimen(s)
and have rendered the above diagnosis(es):

electronic signature

1p/19q Discrepancy		/
1p/19q Malignancy History		/
1p/19q Synchronous Primary No/Yes		/

Source: NCI Genomic Data Commons file 9271ca35-4db6-4f88-bfbc-2747c71485a1 (TCGA-VM-A8CB.581F6861-4408-48DF-BBAB-62707C31090B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).